Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6XG, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6XG-01B (Primary Tumor).

Specimen Date/Time:

ICD-O-3
Adenocarcinoma NOS
8/40/13
Site Esophagus, distal third
CIS
JW 8/8/13

DIAGNOSIS

- (A) ESOPHAGUS (BIOPSY OF BARRETT'S AT 34 CENTIMETERS):
Barrett mucosa of the distinctive intestinalized type with extensive low-grade and focal high-grade columnar epithelial dysplasia.
No invasive carcinoma identified.
- (B) ESOPHAGUS (BIOPSY OF TUMOR):
INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA.
- (C) STOMACH (BIOPSY OF CARDIA):
Oxyntic/fundal mucosa with foveolar hyperplasia, edema, and mild chronic inflammation.
No tumor, Helicobacter pylori, or intestinal metaplasia identified.
- (D) ESOPHAGUS (BIOPSY OF DISTAL ESOPHAGUS AT 30 TO 32 CENTIMETERS):
Squamous epithelium with balloon cells and non-specific reactive epithelial changes.
No tumor or intra-epithelial neutrophils or eosinophils identified.
No lamina propria included in specimens.

GROSS DESCRIPTION

- (A) BARRETT'S @ 34 CM - Three pink-tan soft tissue fragments, each 0.3 cm in greatest dimension. The specimen is submitted entirely in A.
- (B) ESOPH TUMOR - Three friable soft tissue fragments ranging in size from 0.2 to 0.3 cm in greatest dimension. The specimen is submitted entirely in B.
- (C) CARDIA - Four tan-pink soft tissue fragments ranging in size from 0.2 cm to 0.3 cm in greatest dimension. The specimen is submitted entirely in C.
- (D) DISTAL ESOPH 30-32 - Three pink-tan friable soft tissue fragments, 0.3 cm to 0.4 cm in greatest dimension. The specimen is submitted entirely in D.

CLINICAL HISTORY

Esoph tumor.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 279a8c83-5c56-49c9-bba3-f1ef77d4d31e (TCGA-R6-A6XG.5F67CA60-7C4F-4023-96E0-F966EC623E9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).